Somatic mutation profile of tumor specimen TCGA-B0-5116-01A (aliquot TCGA-B0-5116-01A-02D-1421-08) from TCGA case TCGA-B0-5116, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 53.0 years (19,352 days).
Specimen TCGA-B0-5116-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d190f089-b051-4c85-a6b5-f907aed3934e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5116-11A (Solid Tissue Normal), aliquot TCGA-B0-5116-11A-01D-1421-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1af02fe6-dde9-40ae-95b7-5efc2986f7ce

The open-access MAF lists 66 somatic variants for this specimen: 53 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 37, Silent 13, Frame Shift Del 10, Splice Site 3, Nonsense Mutation 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSS2 | c.1007A>G p.Y336C | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs375929217; called by muse, mutect2, varscan2
- ALDH1L1 | c.2239G>A p.G747R | Missense Mutation (SNP) | VAF 68/102 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746651860, COSV56414277; called by muse, mutect2, varscan2
- ALDH8A1 | c.776C>G p.P259R | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55642946; called by muse, mutect2, varscan2
- ALKBH2 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 73/216 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV54358009; called by muse, varscan2
- AP5Z1 | c.922A>C p.S308R | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV62242678; called by muse, mutect2, varscan2
- C11orf16 | c.548A>T p.D183V | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV58168371; called by muse, mutect2, varscan2
- CACNA1S | c.5063G>C p.R1688T | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.026); catalogued as COSV62941737; called by muse, mutect2, varscan2
- CCDC160 | c.836G>T p.S279I | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV66251720, COSV66251791; called by muse, mutect2, varscan2
- CDRT1 | c.1086G>A p.M362I | Missense Mutation (SNP) | VAF 36/377 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55412545; called by muse, mutect2
- CHST8 | c.863T>A p.L288Q | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV52860963; called by muse, mutect2, varscan2
- CPED1 | c.1592A>C p.E531A | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV60007516; called by muse, mutect2, varscan2
- DCAF5 | c.247A>G p.M83V | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV58461645; called by muse, mutect2, varscan2
- EGFR | c.3125G>A p.S1042N | Missense Mutation (SNP) | VAF 67/207 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.451); catalogued as rs1161802556, COSV51823166; called by muse, mutect2, varscan2
- GTF2E2 | c.222G>C p.K74N | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.1); catalogued as COSV63478773; called by muse, mutect2, varscan2
- MACF1 | c.11648A>G p.E3883G (on ENST00000372915; = p.E1816G on NM_012090.5) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | catalogued as COSV57132365; called by muse, mutect2, varscan2
- MAGEC1 | c.2397G>C p.Q799H | Missense Mutation (SNP) | VAF 62/257 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as COSV53577181; called by muse, mutect2, varscan2
- MAP10 | c.2181G>C p.E727D | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV69364304; called by muse, mutect2, varscan2
- MIS18A | c.474T>G p.N158K | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.124); catalogued as COSV51589658; called by muse, mutect2, varscan2
- MRPS26 | c.596G>C p.R199T | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV55662060; called by muse, mutect2, varscan2
- NEK11 | c.1664G>A p.G555E | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV67283615; called by muse, mutect2, varscan2
- NUP98 | c.463G>C p.A155P | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV61435334; called by muse, mutect2, varscan2
- OR4K1 | c.92T>C p.F31S | Missense Mutation (SNP) | VAF 88/845 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV53461324; called by muse, mutect2, varscan2
- OR4K2 | c.260C>G p.T87R | Missense Mutation (SNP) | VAF 70/545 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53850657; called by muse, mutect2, varscan2
- OR51I2 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as COSV58299461; called by muse, mutect2, varscan2
- PBRM1 | c.2507_2528del p.R836Lfs*12 | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | catalogued as COSV56289490; called by mutect2, pindel, varscan2
- PDE6C | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 65/394 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as rs770918079, COSV65114863; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDLIM5 | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763954536, COSV58750137; called by muse, mutect2, varscan2
- PIK3CG | c.212A>T p.K71M | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV63250832; called by muse, mutect2, varscan2
- PPFIA2 | c.3137T>C p.V1046A | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV61042998; called by muse, mutect2, varscan2
- PPP1R9A | c.2349A>T p.K783N | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV56901621; called by muse, mutect2, varscan2
- PTPRK | c.2764+2T>C p.X922_splice (on ENST00000368215 / NM_001291984.2; = p.X923_splice on NM_002844.4) | Splice Site (SNP) | VAF 4/34 reads (12%) | catalogued as COSV63902830; called by muse, mutect2
- PTPRK | c.2764+1G>A p.X922_splice (on ENST00000368215 / NM_001291984.2; = p.X923_splice on NM_002844.4) | Splice Site (SNP) | VAF 4/36 reads (11%) | catalogued as COSV63902843; called by muse, mutect2
- RELB | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV55511727; called by muse, mutect2, varscan2
- REST | c.3079A>G p.S1027G | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58361793; called by muse, mutect2, varscan2
- SEPTIN4 | c.823C>T p.L275F | Missense Mutation (SNP) | VAF 71/169 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.989); catalogued as rs1241263173, COSV58728555; called by muse, mutect2, varscan2
- SLC12A3 | c.658G>T p.G220C | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM116995, COSV52637010; called by muse, mutect2, varscan2
- SLC25A14 | c.852A>C p.L284F | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as rs1569455896, COSV54419242; called by muse, mutect2, varscan2
- TACR1 | c.861C>A p.Y287* | Nonsense Mutation (SNP) | VAF 43/135 reads (32%) | catalogued as COSV59483921; called by muse, mutect2, varscan2
- TACR1 | c.860A>T p.Y287F | Missense Mutation (SNP) | VAF 45/137 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV59483943; called by muse, mutect2, varscan2
- TTN | c.21017C>G p.P7006R (on ENST00000591111; = p.P6079R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | PolyPhen probably damaging (0.999); catalogued as COSV60195786; called by muse, mutect2, varscan2
- ZNF561 | c.1407A>T p.R469S | Missense Mutation (SNP) | VAF 49/212 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV57178268; called by muse, mutect2, varscan2
- ALG10 | c.871_888del p.L291_S296del | In Frame Del (DEL) | VAF 46/306 reads (15%) | called by mutect2, pindel*, varscan2*
- CERKL | c.681del p.H228Ifs*22 | Frame Shift Del (DEL) | VAF 30/182 reads (16%) | called by mutect2, pindel, varscan2
- CORO2B | c.665del p.N222Tfs*4 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- GPATCH1 | c.848del p.G283Afs*6 | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | called by mutect2, pindel
- INPP4B | c.1412del p.L471* | Frame Shift Del (DEL) | VAF 29/93 reads (31%) | called by mutect2, pindel, varscan2
- KPNA1 | c.420_424del p.C141Tfs*4 | Frame Shift Del (DEL) | VAF 18/170 reads (11%) | called by mutect2, pindel, varscan2
- MCAM | c.1092del p.C365Vfs*14 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel, varscan2
- PRR22 | c.894_898delinsG p.A299Lfs*? | Frame Shift Del (DEL) | VAF 10/67 reads (15%) | called by pindel, varscan2*
- RBBP6 | c.16dup p.Y6Lfs*2 | Frame Shift Ins (INS) | VAF 25/115 reads (22%) | called by mutect2, pindel, varscan2
- SUPT6H | c.111_113dup p.X37_splice | Splice Site (INS) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- TMEM79 | c.793del p.S265Lfs*61 | Frame Shift Del (DEL) | VAF 18/119 reads (15%) | called by mutect2, pindel
- TRAF2 | c.47_53del p.Q16Pfs*68 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | called by mutect2, pindel
- ALKBH2 | c.267A>T p.V89= | Silent (SNP) | VAF 32/81 reads (40%) | catalogued as COSV57450140; called by muse, varscan2
- ANKRD13C | c.654C>G p.A218= | Silent (SNP) | VAF 24/173 reads (14%) | catalogued as COSV52033182; called by muse, mutect2, varscan2
- CLIP4 | c.1461C>T p.L487= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as rs770486060, COSV60750727; called by muse, mutect2, varscan2
- CPA1 | c.246C>T p.H82= | Silent (SNP) | VAF 6/97 reads (6%) | catalogued as COSV50572141; called by muse, mutect2
- FKBP15 | c.2670C>A p.I890= | Silent (SNP) | VAF 41/162 reads (25%) | catalogued as COSV53037164; called by muse, mutect2, varscan2
- GLT8D2 | c.517T>C p.L173= | Silent (SNP) | VAF 49/126 reads (39%) | catalogued as rs1184485074, COSV62562503; called by muse, mutect2, varscan2
- KCNH5 | c.696T>A p.V232= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV59768242; called by muse, mutect2, varscan2
- KRTAP5-9 | c.465C>A p.S155= | Silent (SNP) | VAF 36/187 reads (19%) | catalogued as COSV73200236; called by muse, mutect2, varscan2
- MATR3 | c.163T>C p.L55= | Silent (SNP) | VAF 77/205 reads (38%) | catalogued as COSV63078460; called by muse, mutect2, varscan2
- MUC16 | c.10422C>T p.L3474= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs890737234, COSV67479690; called by muse, mutect2, varscan2
- SPTBN5 | c.9504G>A p.L3168= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs1488523028, COSV58024570; called by muse, mutect2, varscan2
- TSEN15 | c.261C>A p.L87= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV62294531; called by muse, mutect2, varscan2
- TTI1 | c.2355A>G p.L785= | Silent (SNP) | VAF 65/216 reads (30%) | catalogued as rs1487062208, COSV65062503; called by muse, mutect2, varscan2
